Surgical pathology report (de-identified scan), TCGA case TCGA-CZ-5459, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Harvard, specimen TCGA-CZ-5459-01A (Primary Tumor).

[page 1 of 3]
Accession Number: [REDACTED] Report Status: Amend/Addendum
Type: Surgical Pathology
Specimen Type: Kidney, partial or total resection
Procedure Date: [REDACTED]
Ordering Provider: [REDACTED]

CASE: [REDACTED]
PATIENT: X

TCGA-CZ-5459

***** Added Report ** [REDACTED]

PATHOLOGIC DIAGNOSIS:

SPECIMEN DESIGNATED "RIGHT KIDNEY":
RENAL CELL CARCINOMA, clear cell type (4.5 cm),
Fuhrman nuclear grade 3 (of 4).
Vascular and ureteral margins are negative for tumor.
The tumor does not invade the renal capsule or into
the sinus adipose tissue.
The tumor invades into the main renal vein.
No lymphovascular invasion identified.
AJCC Classification (6th Edition): T3b Nx MX.
The non-neoplastic kidney will be evaluated by Renal Pathology, and the
findings will be reported in an addendum.

CLINICAL DATA:

History: Right renal mass.
Operation: Right radical nephrectomy with vena cava resection.
Operative Findings: None given.
Clinical Diagnosis: Right renal mass with IVC extension.

ORGAN/TISSUE SUBMITTED:
A/1. Right kidney.

GROSS DESCRIPTION:

The specimen is received fresh, labeled with the patient's name, unit number, and "#1. Right renal mass with tumor of thrombus", and consists of a radical nephrectomy specimen measuring 19.5 x 2.0 x 4.5 cm. The ureter measures 1.0 cm in length x 0.5 cm in diameter, renal artery measures 0.9 cm in length x 0.5 cm in diameter, and renal vein measures 1.1 cm in length and 2.2 cm in diameter. There is an adherent yellow/black/red thrombus clogging the renal vein. Bisecting the kidney along the ureter reveals a well-circumscribed but multinodular and focally cystic orange/yellow/tan tumor mass measuring 4.5 cm x 2.5 cm x 2.4 cm. Tumor is seen to abut the renal vein in close association with the thrombus. There are foci suspicious for invasion of tumor in to the renal pelvis adipose tissue. Grossly the tumor does not invade through the renal capsule and the Gerota's fascia and perirenal fat are freely mobile. The Gerota's fascia is inked black. Representative sections of tumor are submitted to tissue bank, cytogenetics. Representative sections of normal kidney are submitted to tissue bank, electron microscopy and immunofluorescence. Sectioning through the perirenal fat reveals an absence of lymph nodes or adrenal gland. Gross photographs are taken.

Micro A1: Vascular and ureteral margins, 4 frags total, [REDACTED]
Micro A2: Tumor and renal pelvis, 1 frag, [REDACTED]
Micro A3: Tumor, renal vein, and thrombus, 1 frag, [REDACTED]
Micro A4: Tumor and adjacent normal kidney, 1 frag, [REDACTED]
Micro A5: Tumor, perirenal fat, and Gerota's fascia, 1 frag, [REDACTED]
Micro A6 and A7: Additional representative sections of tumor, 2 frags per cassette, [REDACTED]
Micro A8: Normal kidney, 1 frag, [REDACTED]
Micro A9: Ureteral margin and additional vascular margins, 3 frags, [REDACTED]

By his/her signature below, the senior physician certifies that he/she personally conducted a microscopic examination ("gross only" exam if so stated) and rendered or confirmed the diagnosis(es)

[page 2 of 3]
atrophy. Approximately 10-15% of the cortical parenchyma shows tubular atrophy and interstitial fibrosis. Arteries and arterioles exhibit moderate degree of sclerosis.

TCGA-CZ-5459

[page 3 of 3]
[REDACTED]

Accession Number: [REDACTED]

Report Status: Final

Type: Cytogenetics

CASE: [REDACTED]

PATIENT: [REDACTED]

Cytogenet. Lab: [REDACTED]

KARYOTYPE: 44,X,-Y,-3,der(17)t(3;17)(q1?1;p1?3)(10)

METAPHASES COUNTED: 10

ANALYZED: 5

SCORED: 5

BANDING: GTG

INTERPRETATION:

All metaphases contained clonal aberrations that included loss of the short arm of chromosome 3, which is a characteristic finding in renal cell carcinoma, clear cell type.

COMMENTS:

Mosaicism and small chromosome anomalies may not be detectable using the standard methods employed. Chromosome analysis was performed at a level of 400 bands or greater.

INDICATION FOR TEST:

RCC

[REDACTED]

Source: NCI Genomic Data Commons file 0c3bec2d-8687-45ec-b304-2cdee61344ab (TCGA-CZ-5459.C0241502-26E1-4A32-BA74-907B5D034183.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).